Surgical pathology report (de-identified scan), TCGA case TCGA-W2-A7HD, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Medical College of Wisconsin, specimen TCGA-W2-A7HD-01A (Primary Tumor).

[page 1 of 2]
Results History

SURG PATH FINAL REPORT

Entry Information

Entry Date and Time

Lab Status
Final result

Entered by

Component Results

SURG PATH FINAL REPORT:

Accession #:

Specimen:

Date of Procedure:

Performing Clinician:

A. Right adrenal

Clinical Notes:

Fresh tissue saved for tissue bank. Pre-op
diagnosis: Right adrenal mass.

Diagnosis:

A. Right adrenal, adrenalectomy:
- Pheochromocytoma.

Note: there is no evidence of capsular or
vascular invasion, tumor cell necrosis, or
significant mitotic activity.

(Electronically signed by)

Verified:

Gross:

A. The specimen is labeled "right adrenal." Received in
in a petrie dish and transferred to formalin is a
previously incised and disrupted 29.0 gram portion of
adrenal with attached adipose tissue. The adrenal is 4.5 x
4.0 x 1.5 cm. The disrupted adrenal is composed of a thin
orange-tan cortical rim with a central soft tan-gray
medullary tissue. A portion of the adrenal is taken by
tissue bank. Representative sections of the
remaining adrenal are submitted in cassettes A1 through A6.

Microscopic:

A histological examination has been performed.

ICD-O.3

Pheochromocytoma NOS
8700/0

Site (R) Adrenal gland NOS
C74.9
9/14/13

[page 2 of 2]
Administrative Notes:

Accession #:

CPT:

No charge codes are associated with this case.

Entry Information

Entry Date and Time

Lab Status
In process

Entered by

Criteria	W 8/29/13	Yes	No

Source: NCI Genomic Data Commons file 17aeb561-fbc1-467d-8dc1-7a97247c658b (TCGA-W2-A7HD.A91DACE6-C322-45FD-A5CD-3DB6F42B18E9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).